Somatic mutation profile of tumor specimen MBCProject_0297_T2_WES (aliquot MBCProject_0297_T2_WES_1) from CMI case MBCProject_0297, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 36.7 years (13,418 days).
Specimen MBCProject_0297_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c5b9ad4-b110-4a78-aba0-1bb46ec4cd01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0297_SALIVA (Saliva), aliquot MBCProject_0297_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a09200f1-f8cc-4dfd-a11d-269aeb6b356c

The open-access MAF lists 129 somatic variants for this specimen: 88 protein-altering or splice-affecting, 25 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 25, Intron 11, Nonsense Mutation 8, Frame Shift Del 5, Splice Site 2, RNA 2, Splice Region 2, 3'UTR 2, In Frame Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 23/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574370650; called by muse, mutect2
- BRINP2 | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.102); catalogued as COSV64180475; called by muse, mutect2, varscan2
- CCDC120 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1246429855; called by muse, mutect2, varscan2
- CEP350 | c.7054G>C p.E2352Q | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62602197, COSV62604502; called by muse, mutect2, varscan2
- COL18A1 | c.1354C>T p.R452C (on ENST00000359759 / NM_130444.3; = p.R217C on NM_030582.4) | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1020212554; called by muse, mutect2
- EXT2 | c.112A>T p.I38F (on ENST00000343631; = p.I71F on NM_000401.3) | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as CD044269; called by muse, mutect2
- EYS | c.5354C>A p.S1785* | Nonsense Mutation (SNP) | VAF 18/216 reads (8%) | catalogued as COSV58195959; called by muse, mutect2
- FRMPD4 | c.3308A>G p.E1103G | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs906447958; called by muse, mutect2, varscan2
- HOXD13 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.074); catalogued as COSV66832416; called by muse, mutect2, varscan2
- INHBB | c.837G>C p.Q279H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs542203870; called by muse, mutect2, varscan2
- OCA2 | c.1843-1G>A p.X615_splice | Splice Site (SNP) | VAF 63/327 reads (19%) | catalogued as CS097333, COSV62347306; called by muse, mutect2, varscan2
- PCDH19 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 39/347 reads (11%) | catalogued as COSV55263535; called by muse, mutect2, varscan2
- PCSK9 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53760926; called by muse, mutect2, varscan2
- PML | c.2488C>A p.Q830K | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV104390188; called by muse, mutect2, varscan2
- PTPN6 | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 25/271 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100017118; called by muse, mutect2
- RFPL2 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV50709893; called by muse, mutect2
- SGSM3 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as rs779800828; called by muse, mutect2
- SLC38A3 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1390349901, COSV68844160; called by muse, mutect2, varscan2
- SLITRK6 | c.684G>C p.Q228H | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV68390991; called by muse, mutect2
- SLX4 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs532023958; called by muse, mutect2, varscan2
- TEAD4 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV63280325; called by muse, mutect2, varscan2
- TMTC3 | c.995T>C p.M332T | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs761912189; called by muse, mutect2
- TNFRSF25 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs758747550; called by muse, mutect2, varscan2
- TRIM4 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs746597075, COSV57209766, COSV57210449; called by muse, mutect2
- TRMT5 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV54203247; called by muse, mutect2, varscan2
- ZNF140 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1171940667; called by muse, mutect2
- ACTN3 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- AJUBA | c.1015A>C p.I339L | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- AKAP6 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 57/191 reads (30%) | called by muse, mutect2, varscan2
- AMBN | c.571-1G>A p.X191_splice | Splice Site (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- AP3B2 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 51/387 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- ARHGAP9 | c.1933C>A p.L645M (on ENST00000393797 / NM_001319850.2; = p.L626M on NM_032496.4) | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- BST1 | c.619_626delinsTTTTTTTT p.A207_Y209delinsFFF | Missense Mutation (ONP) | VAF 4/32 reads (13%) | called by pindel, varscan2*
- CCDC154 | c.1414_1416dup p.K472dup | In Frame Ins (INS) | VAF 32/94 reads (34%) | called by pindel, varscan2
- CD101 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTNAP5 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- COL15A1 | c.3211G>T p.V1071F | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- COMMD3 | c.315+7T>A | Splice Region (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- CSF2RB | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 18/199 reads (9%) | called by muse, mutect2
- DNAH17 | c.4234A>T p.K1412* | Nonsense Mutation (SNP) | VAF 24/210 reads (11%) | called by muse, varscan2
- EPG5 | c.3889_3902del p.Q1297Tfs*3 | Frame Shift Del (DEL) | VAF 23/145 reads (16%) | called by mutect2, pindel, varscan2
- ESPL1 | c.2759C>G p.S920* | Nonsense Mutation (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- FAT1 | c.8072T>A p.V2691D | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- FDXACB1 | c.1071T>G p.D357E | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGA | c.2421G>T p.W807C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GK3P | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 22/345 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- GPT | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 52/964 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.036); called by muse, mutect2
- HCFC1 | c.1280G>T p.S427I | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2
- HLTF | c.2726_2737delinsACTG p.L909Hfs*2 | Nonsense Mutation (DEL) | VAF 22/130 reads (17%) | called by pindel, varscan2*
- IDE | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IL2 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KAT6A | c.4294A>T p.T1432S | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KREMEN1 | c.611T>C p.I204T (on ENST00000407188; = p.I206T on NM_032045.5) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- LRIG3 | c.2953T>C p.F985L | Missense Mutation (SNP) | VAF 19/351 reads (5%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2
- LTB4R | c.387del p.T130Pfs*29 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel*
- LYST | c.1068G>C p.L356F | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1766T>C p.I589T | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MUSK | c.2382G>T p.E794D | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- NCOA6 | c.2151G>A p.M717I | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2
- NEURL4 | c.2673_2698del p.S891Rfs*54 | Frame Shift Del (DEL) | VAF 29/156 reads (19%) | called by mutect2, pindel
- NGLY1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2
- NSL1 | c.177del p.K59Nfs*61 | Frame Shift Del (DEL) | VAF 52/509 reads (10%) | called by mutect2, pindel, varscan2
- OPLAH | c.2035C>G p.L679V | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2
- PCDHAC2 | c.1643C>A p.T548N | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- PIEZO2 | c.890C>G p.A297G | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PIGV | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHH1 | c.3063G>C p.E1021D | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PLPBP | c.455-4G>C | Splice Region (SNP) | VAF 45/279 reads (16%) | called by muse, mutect2, varscan2
- PNMA3 | c.1378T>A p.S460T | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2
- RAPGEF3 | c.2185_2197del p.G729Sfs*37 (on ENST00000389212; = p.G687Sfs*37 on NM_006105.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 34/224 reads (15%) | called by mutect2, pindel, varscan2
- RPS9 | c.53G>C p.R18T | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2
- SCD5 | c.147T>A p.N49K | Missense Mutation (SNP) | VAF 64/593 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- SHFL | c.599C>G p.T200S | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SMARCC2 | c.1359G>C p.K453N | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SMG6 | c.3452G>C p.G1151A | Missense Mutation (SNP) | VAF 38/329 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMG9 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SOGA1 | c.1862_1876del p.E621_S625del | In Frame Del (DEL) | VAF 21/219 reads (10%) | called by mutect2, pindel
- SOX10 | c.1370A>C p.Q457P | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SSH3 | c.466T>G p.S156A | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, varscan2
- TBC1D7 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRIM39 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- TRIM60 | c.157T>A p.C53S | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM71 | c.1872C>A p.D624E | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC28 | c.5567T>C p.M1856T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VPS39 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2
- ZEB1 | c.2681A>G p.K894R | Missense Mutation (SNP) | VAF 31/340 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZFPL1 | c.223C>G p.H75D | Missense Mutation (SNP) | VAF 99/392 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF425 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ACACA | c.2619G>A p.L873= | Silent (SNP) | VAF 29/364 reads (8%) | catalogued as rs756204117; called by muse, mutect2
- ANO8 | c.1920G>A p.G640= | Silent (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
- BAHCC1 | c.3681A>T p.S1227= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- BCAR3 | c.1707C>G p.V569= | Silent (SNP) | VAF 25/240 reads (10%) | catalogued as COSV53075853; called by muse, mutect2, varscan2
- CACNA1E | c.2235G>T p.S745= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as rs772107111, COSV62423219; called by muse, mutect2, varscan2
- CACNG1 | c.567C>T p.F189= | Silent (SNP) | VAF 139/593 reads (23%) | called by muse, mutect2, varscan2
- DIDO1 | c.3138G>A p.T1046= | Silent (SNP) | VAF 18/249 reads (7%) | catalogued as rs754772333; called by muse, mutect2
- FAM180B | c.381C>G p.S127= | Silent (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- FDXACB1 | c.786G>A p.L262= | Silent (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- KCNC3 | c.1413C>T p.R471= | Silent (SNP) | VAF 117/607 reads (19%) | called by muse, mutect2, varscan2
- KCNS2 | c.555G>A p.L185= | Silent (SNP) | VAF 37/547 reads (7%) | catalogued as rs751798846; called by muse, mutect2
- MEX3B | c.234C>A p.V78= | Silent (SNP) | VAF 51/416 reads (12%) | catalogued as COSV100314061; called by muse, mutect2, varscan2
- MORC2 | c.2490C>T p.Y830= (on ENST00000397641 / NM_001303256.3; = p.Y768= on NM_014941.3) | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs1254111017; called by muse, mutect2, varscan2
- MRPL49 | c.282C>T p.I94= | Silent (SNP) | VAF 97/419 reads (23%) | called by muse, mutect2, varscan2
- NEURL2 | c.774G>A p.V258= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as COSV51941756; called by muse, mutect2, varscan2
- NRROS | c.1773C>T p.L591= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- OSCAR | c.729G>T p.P243= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99500039; called by muse, mutect2
- PRDM9 | c.1242G>A p.Q414= | Silent (SNP) | VAF 37/302 reads (12%) | catalogued as COSV57012984; called by muse, mutect2, varscan2
- RFX3 | c.2076C>T p.A692= | Silent (SNP) | VAF 81/259 reads (31%) | called by muse, mutect2, varscan2
- SGCG | c.108C>A p.L36= | Silent (SNP) | VAF 15/190 reads (8%) | catalogued as COSV54571227; called by muse, mutect2
- SPTSSA | c.33G>A p.K11= | Silent (SNP) | VAF 115/586 reads (20%) | catalogued as rs376851624; called by muse, mutect2, varscan2
- SYTL1 | c.1107G>T p.V369= (on ENST00000543823; = p.V357= on NM_032872.3) | Silent (SNP) | VAF 35/238 reads (15%) | called by muse, mutect2, varscan2
- WDR86 | c.843C>G p.L281= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- ZNF425 | c.1269C>T p.F423= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- ZNF440 | c.501T>A p.T167= | Silent (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2
- ARMCX4 | c.1038+1856G>C | Intron (SNP) | VAF 58/223 reads (26%) | called by muse, mutect2, varscan2
- DST | c.1146-178T>G | Intron (SNP) | VAF 16/238 reads (7%) | catalogued as rs766639572; called by muse, mutect2
- FAM160A2 | c.2215+234G>C | Intron (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- FAM3B | c.-76C>T | 5'UTR (SNP) | VAF 14/62 reads (23%) | catalogued as rs1241431176; called by muse, mutect2, varscan2
- KHSRP | c.*592C>G | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- LRRC37B | c.2124-4135G>A | Intron (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- MIR182 | n.25T>C | RNA (SNP) | VAF 28/199 reads (14%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.759+534G>A | Intron (SNP) | VAF 34/158 reads (22%) | catalogued as rs753896137; called by muse, mutect2, varscan2
- NRP1 | c.1864+100G>C | Intron (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- PLEKHM1 | c.*1065G>C | 3'UTR (SNP) | VAF 70/458 reads (15%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1297-37C>T | Intron (SNP) | VAF 24/159 reads (15%) | catalogued as rs1377258097; called by muse, mutect2, varscan2
- RDX | c.1091-10T>G | Intron (SNP) | VAF 33/236 reads (14%) | called by muse, mutect2, varscan2
- RPS7 | c.507+40A>G | Intron (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2
- SH2D3C | c.516-5396C>G | Intron (SNP) | VAF 28/189 reads (15%) | catalogued as COSV59121080; called by muse, mutect2, varscan2
- SPATA31C2 | n.2969C>A | RNA (SNP) | VAF 26/196 reads (13%) | called by muse, mutect2, varscan2
- ZNF207 | c.780+57T>C | Intron (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
